Surgical pathology report (de-identified scan), TCGA case TCGA-X7-A8DJ, project TCGA-THYM (Thymoma), tissue source site ABS IUPUI, specimen TCGA-X7-A8DJ-01A (Primary Tumor).

[page 1 of 2]
Operative Procedure:
Sternotomy, mediastinal dissection.

Pre-Operative Diagnosis:
As below

Post-Operative Diagnosis:
As below

Specimen Received:
Mediastinal mass

Final Pathologic Diagnosis:
Mediastinum, anterior, mass, resection:

Thymoma, WHO mixed type AB

THYMUS: Resection

Specimen: Thymus

Procedure: Thymectomy

Specimen Integrity: Intact

Specimen Weight: 220 grams

Tumor Size: 9 x 6.5 by up to 2.4 cm

Histologic Type: Type AB thymoma

Capsular invasion: Not identified

Tumor Extension: Not identified

Margins: Uninvolved by tumor. Distance of tumor from closest margin: 0.3 cm

Treatment Effect: Not applicable

Lymph-Vascular Invasion: Not identified

Regional Lymph Nodes: No lymph nodes submitted or found

Modified Masaoka Stage Pathologic thymoma Staging:

Stage I: Grossly and microscopically encapsulated (including microscopic invasion into but not through the capsule)

Pathologic Staging (pTNM): Not applicable (applied only for thymic carcinomas)

Implants/Distant Metastasis: Not identified

Additional Pathologic Findings: None

Ancillary Studies: Synaptophysin and chromogranin are negative in the type A component (staining with keratin AE1-AE3)

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Gross Description:

The specimen is received in a formalin filled container labeled with the patient's name, and additionally labeled "mediastinal mass"

ICD-O 3
Thymoma, type AB NOS 8582/1
Site: ^{site} Mediastinum, anterior C38.1
^{path} Thymus C37.9
Sp J 6/13/14

[page 2 of 2]
and consists of a previously inked, previously incised portion of yellow-tan tissue that is 220 grams and has overall dimensions of 15 x 11 by up to 5 cm. The specimen is additionally sectioned to reveal a pink-tan, lobulated, fairly well delineated mass that has overall dimensions of 9 x 6.5 by up to 2.4 cm. This mass abuts the inked external surface in multiple areas. The mass is remarkable for a central area of degeneration that is 2 cm in greatest dimension. The mass appears to be partially encapsulated. The remaining cut surfaces are yellow-tan and lobulated.

Representative sections are submitted as follows:

- 1-5 mass to include areas of inked external surface and degeneration;
- 6-7 uninvolved fibroadipose tissue.

Please note, a portion of the specimen has been collected by the tissue bank.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

END OF REPORT

Taken: DOB: Gender: M

Criteria	lw 10/31/13	Yes	No
HPA Discrepancy			☒

Source: NCI Genomic Data Commons file a9449725-9612-4190-b275-19e7277c7361 (TCGA-X7-A8DJ.757DF97F-DA22-4F8F-AD0F-C93BC329150B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).